TARGET case TARGET-30-PATBJI — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c2480e45-5b2c-52ba-8950-f16a7dc67c73

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Age at index: 0 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C49.6; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Classification of tumor: primary; Age at diagnosis: 0.2 years (88 days); Year of diagnosis: 2009; Days to last follow up: 3,137 days (8.6 years); Cog neuroblastoma risk group: Low Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 2A; Mitosis karyorrhexis index: Low.
   Pathology details: Percent tumor nuclei: 60.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (2 entries)
- Days to follow up: 90 days; Days to first event: 90 days; First event: Progression.
- Days to follow up: 3,137 days (8.6 years); Year of follow up: 2018.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PATBJI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PATBJI-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 3137
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.44
- Histology: Favorable
- MKI: Low
- Site of Relapse: Primary site
